Gene-level copy-number profile of tumor specimen ALCH-B2WB-TTP1-A from ALCHEMIST case ALCH-B2WB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.3 years (22,772 days).
Specimen ALCH-B2WB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4582089d-b3cc-44c0-91f4-99c0a32874b5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2WB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/dd115e28-c308-4f3e-a56b-b354dc38f881

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 22,349; copy number 2: 29,980; copy number 3: 5,758; copy number 4: 118; copy number 5: 13; copy number 6: 88; copy number 8: 32.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:113,570,190–113,590,019, 1 gene (within-gene range 0–1): AL162727.2.
- chr11:17,719,571–17,722,136, 1 gene: MYOD1.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr21:43,414,483–43,427,131, 1 gene: SIK1.
- chr22:30,239,194–30,246,998, 3 genes: LIF-AS1, LIF, AC004264.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 133 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,568,117–74,766,678, 5 genes, copy number 5: ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:33,924,227–39,432,500, 120 genes, copy number 6–8 (broad region; genes not listed).
- chr19:1,065,923–1,106,791, 3 genes, copy number 5: ARHGAP45, POLR2E, GPX4.
- chr21:43,446,601–43,453,902, 1 gene, copy number 5: LINC00319.

Autosomal genes at a single copy (total copy number 1): 22,348. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
